Gene-level copy-number profile of tumor specimen TCGA-43-2581-01A from TCGA case TCGA-43-2581, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 47.8 years (17,447 days).
Specimen TCGA-43-2581-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.0a5b6290-81be-484a-b05d-2b4228380edf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-43-2581-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9f04cb3c-57c5-40f3-bb9d-8bec8e44e5ab

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 90; copy number 1: 20,973; copy number 2: 34,573; copy number 3: 3,347; copy number 4: 670; copy number 5: 126; copy number 6: 2; copy number 7: 1; copy number 12: 6; copy number 16: 2; copy number 19: 24; copy number 21: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-43-2581-01A-01D-0844-01): tumor purity 0.29, ploidy 3.77, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 90 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:43,923,792–48,143,229, 90 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 164 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:57,723,761–57,984,761, 24 genes, copy number 19 (within-gene range 1–19): AGAP2, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:58,920,639–59,064,238, 3 genes, copy number 21 (within-gene range 3–22): AC068305.2, RPS6P22, AC068305.1.
- chr12:61,231,159–62,279,150, 7 genes, copy number 7–12 (within-gene range 1–12): AC090017.1, DUX4L52, AC090629.1, TAFA2, RPL21P104, KRT8P19, RPS3P6.
- chr12:64,654,060–64,696,550, 2 genes, copy number 16: AC078962.3, AC025262.2.
- chr17:52,390,515–52,899,588, 2 genes, copy number 6: LINC01982, LINC02089.
- chr17:53,952,936–55,872,939, 22 genes, copy number 5: AC023934.1, ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1.
- chr17:67,337,916–70,241,761, 73 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:71,298,156–73,312,005, 31 genes, copy number 5: RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1, ATG12P1, POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4.

Autosomal genes at a single copy (total copy number 1): 18,552. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
